Gene-level copy-number profile of tumor specimen TCGA-DD-AAVY-01A from TCGA case TCGA-DD-AAVY, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 56.7 years (20,709 days).
Specimen TCGA-DD-AAVY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.0485a5c4-f8ba-4719-b1d5-385c592256ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AAVY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9d64e49c-7914-4c7b-8ddb-e11cf5a361ea

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,532; copy number 2: 45,312; copy number 3: 5,226; copy number 4: 4,073; copy number 5: 1,677.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AAVY-01A-11D-A40Q-01): tumor purity 1, ploidy 2.23, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,677 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,042,184–241,595,642, 62 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:44,727,921–60,546,660, 206 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr6:60,789,805–60,942,327, 3 genes, copy number 5 (within-gene range 1–5): AL512427.2, AL512427.1, RBBP4P3.
- chr8:34,174,886–34,207,513, 1 gene, copy number 5 (within-gene range 1–5): AC087855.2.
- chr8:34,322,992–34,323,642, 1 gene, copy number 5: RPL10AP3.
- chr8:35,080,592–35,093,509, 1 gene, copy number 5: AC099685.1.
- chr8:35,254,344–35,256,605, 1 gene, copy number 5: AC090740.1.
- chr8:36,378,069–36,779,209, 2 genes, copy number 5 (within-gene range 1–5): AC090809.1, RPL23P10.
- chr8:40,298,697–41,309,473, 11 genes, copy number 5: SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P.
- chr8:41,653,220–139,463,016, 1,389 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,644. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
